Somatic mutation profile of tumor specimen TCGA-D5-6540-01A (aliquot TCGA-D5-6540-01A-11D-1719-10) from TCGA case TCGA-D5-6540, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 66.5 years (24,282 days).
Specimen TCGA-D5-6540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b750585d-c520-42f6-82db-15fc6ec31fc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6540-10A (Blood Derived Normal), aliquot TCGA-D5-6540-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e71d434b-be8f-45a1-ab48-850915c07c1d

The open-access MAF lists 1,625 somatic variants for this specimen: 1,142 protein-altering or splice-affecting, 356 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 775, Silent 356, Frame Shift Del 243, Frame Shift Ins 60, Intron 49, Nonsense Mutation 41, 3'UTR 36, RNA 18, Splice Region 10, 5'UTR 10, 5'Flank 9, Splice Site 7.

Variants (750 of 1,625; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- BAG3 | c.72del p.G25Dfs*186 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs727502897; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BMPR2 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as rs1085307149, CM060863, COSV65812535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLCNKB | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs121909132, CM970321, COSV65161552; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DBT | c.360del p.K120Nfs*6 | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | catalogued as rs398123668; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 84/114 reads (74%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAA | c.258del p.N87Tfs*55 | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRT2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852629, CM941018, COSV59012143; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel
- MYH7 | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880781, CM1411010; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 21/168 reads (13%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 73/147 reads (50%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTOF | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as rs397515582, CM091226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHYKPL | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201105857, CM1212105; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 40/148 reads (27%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRNT1 | c.1252del p.S418Vfs*11 | Frame Shift Del (DEL) | VAF 67/172 reads (39%) | catalogued as rs876661298, CM1411168, COSV51642664; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 90/172 reads (52%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA13 | c.7550C>A p.T2517K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.471); catalogued as COSV71292730; called by muse, mutect2, varscan2
- ABCA2 | c.4750G>T p.G1584W (on ENST00000614293; = p.G1554W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); catalogued as COSV55805026; called by muse, mutect2, varscan2
- ABCA7 | c.3353G>A p.R1118Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1339404731, COSV54035270; called by muse, mutect2, varscan2
- ABCC11 | c.3496C>A p.R1166S | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs146149363; called by muse, mutect2, varscan2
- ABCG2 | c.1253del p.N418Mfs*16 | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | catalogued as COSV52950407; called by mutect2, pindel, varscan2
- ABR | c.205dup p.D69Gfs*9 | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | catalogued as rs766403834; called by mutect2, varscan2
- AC004922.1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1368025200, COSV53558289; called by muse, mutect2, varscan2
- ACAD9 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.78); catalogued as COSV58309405; called by muse, mutect2, varscan2
- ACAT2 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs748574249, COSV58460129; called by muse, mutect2, varscan2
- ACVR2B | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 54/146 reads (37%) | catalogued as rs1250515265, COSV61700920; called by muse, mutect2, varscan2
- ADAM21 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50803800; called by muse, mutect2, varscan2
- ADAMTS15 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54508674; called by muse, mutect2, varscan2
- ADAMTS20 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV67136996; called by muse, mutect2, varscan2
- ADAMTSL4 | c.972del p.H324Qfs*19 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as COSV55005086; called by mutect2, pindel, varscan2
- ADCY5 | c.1959G>T p.K653N | Missense Mutation (SNP) | VAF 218/556 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV59202432; called by muse, mutect2, varscan2
- ADCYAP1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as rs1487295797, COSV52487224; called by muse, mutect2, varscan2
- ADGRE5 | c.1139G>A p.R380H (on ENST00000242786 / NM_078481.4; = p.R287H on NM_001784.5) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs149991001; called by muse, mutect2, varscan2
- ADGRG2 | c.2473C>T p.R825* (on ENST00000379869 / NM_001079858.3; = p.R822* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 154/213 reads (72%) | catalogued as COSV61340215, COSV61340629; called by muse, mutect2, varscan2
- ADGRG5 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as rs765140417, COSV61084194; called by muse, mutect2, varscan2
- ADRM1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs1202290473, COSV53368503; called by muse, mutect2, varscan2
- ADTRP | c.333T>A p.D111E | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57645135; called by muse, mutect2, varscan2
- AGAP2 | c.2771G>A p.R924H (on ENST00000547588 / NM_001122772.2; = p.R568H on NM_014770.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV57730723; called by muse, mutect2, varscan2
- AGPAT5 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 72/136 reads (53%) | catalogued as rs752941173, COSV53446129; called by muse, mutect2, varscan2
- AGRN | c.5915C>T p.A1972V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65071674; called by muse, mutect2, varscan2
- AHNAK | c.12644C>T p.A4215V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as rs1565228158; called by muse, mutect2, varscan2
- AHR | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV54125572; called by muse, mutect2, varscan2
- AK9 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs1562568442, COSV53422965; called by muse, mutect2
- AKAP17A | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs1472914552, COSV58311400; called by muse, mutect2, varscan2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- ALOX15B | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs577207398, COSV66479988; called by muse, mutect2, varscan2
- ALPK1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1253598326, COSV51585117; called by muse, mutect2, varscan2
- AMACR | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59462450; called by muse, mutect2, varscan2
- AMPD2 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1557938355, COSV56649909; called by muse, mutect2, varscan2
- AMZ1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs751923707, COSV56685024; called by muse, mutect2, varscan2
- ANGPT1 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV52451722; called by muse, varscan2
- ANGPTL7 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160600384, COSV63876228; called by muse, mutect2, varscan2
- ANKK1 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376599631, COSV58270177, COSV58273681; called by muse, mutect2, varscan2
- ANKRD12 | c.2104A>T p.K702* | Nonsense Mutation (SNP) | VAF 234/826 reads (28%) | catalogued as COSV50839626; called by mutect2, varscan2
- ANKRD17 | c.2888C>A p.P963H | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.921); catalogued as COSV58225881; called by muse, mutect2, varscan2
- ANO8 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV50194100; called by muse, varscan2
- ANO8 | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV50194212, COSV99344464; called by muse, varscan2
- ANXA13 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs992360945, COSV51623321; called by muse, mutect2, varscan2
- APAF1 | c.1731T>G p.Y577* (on ENST00000551964 / NM_181861.2; = p.Y566* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 76/201 reads (38%) | catalogued as COSV59666824; called by muse, mutect2, varscan2
- APOBEC3F | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs774288237, COSV57910582; called by muse, mutect2, varscan2
- ARCN1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs782690322, COSV50616581; called by muse, mutect2, varscan2
- ARHGAP22 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV50966942; called by muse, mutect2, varscan2
- ARHGAP33 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.983); catalogued as rs374221923; called by muse, mutect2, varscan2
- ARHGAP44 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs776234269, COSV52394532; called by muse, mutect2, varscan2
- ARHGEF10L | c.191del p.P64Hfs*2 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | catalogued as rs943131944; called by pindel, varscan2
- ARHGEF17 | c.5029G>A p.A1677T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV55236150; called by muse, mutect2, varscan2
- ARHGEF25 | c.92del p.G31Dfs*48 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs748506876, COSV99677997; called by mutect2, pindel, varscan2
- ARHGEF33 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV67257920; called by muse, mutect2, varscan2
- ARHGEF4 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.424); catalogued as COSV58127661; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as COSV61389445; called by pindel, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 62/141 reads (44%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARSB | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53727774; called by muse, mutect2, varscan2
- ASB1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1031302620, COSV52827966; called by muse, mutect2, varscan2
- ASB13 | c.361del p.L121Cfs*6 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as COSV63090510; called by mutect2, varscan2
- ASPDH | c.457C>T p.H153Y (on ENST00000389208 / NM_001114598.2; = p.H48Y on NM_001024656.3) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65350577; called by muse, mutect2, varscan2
- ASPM | c.1320A>T p.E440D | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV54135872; called by muse, mutect2, varscan2
- ASTN1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56079744; called by muse, mutect2, varscan2
- ATAD2 | c.638_639+1del p.X213_splice | Splice Site (DEL) | VAF 96/446 reads (22%) | catalogued as rs1243596943; called by pindel, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF5 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100352268; called by muse, mutect2, varscan2
- ATF6 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV63409353; called by muse, mutect2, varscan2
- ATP10A | c.2800G>A p.V934M | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs145756944; called by muse, mutect2, varscan2
- ATP2A1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1401049227; called by muse, mutect2
- ATP2A1 | c.1712dup p.K572Efs*9 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | catalogued as rs772363145; called by mutect2, varscan2
- ATP2A2 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as CM151561, COSV58046675; called by muse, mutect2, varscan2
- BAMBI | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65003338; called by muse, mutect2, varscan2
- BICC1 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV54065793; called by muse, mutect2, varscan2
- BICRA | c.2470C>A p.P824T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1457546256, COSV67605957; called by muse, mutect2, varscan2
- BOC | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs926466843, COSV56356072; called by muse, mutect2, varscan2
- BTN2A2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs895640925, COSV61858212; called by muse, mutect2, varscan2
- BTNL9 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs369125172; called by muse, mutect2, varscan2
- C14orf28 | c.747C>T p.H249= | Splice Region (SNP) | VAF 72/202 reads (36%) | catalogued as COSV57333992; called by muse, mutect2, varscan2
- C5orf15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as rs775456361, COSV51548917; called by muse, mutect2, varscan2
- C5orf34 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749338613, COSV60931544; called by muse, mutect2, varscan2
- C7orf25 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV63273657, COSV63274313; called by muse, mutect2, varscan2
- CACNA1S | c.2963G>A p.R988H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747618077, COSV62938239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.034); catalogued as rs897880041, COSV56639932; called by muse, mutect2, varscan2
- CAP2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141863829, COSV57729659; called by muse, mutect2, varscan2
- CAPZB | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as COSV51646188; called by muse, mutect2, varscan2
- CASZ1 | c.5034G>C p.E1678D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV65458017; called by muse, mutect2, varscan2
- CATSPERE | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63676966, COSV63680750; called by muse, mutect2, varscan2
- CATSPERG | c.2651del p.P884Qfs*18 | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | catalogued as COSV53051477; called by mutect2, pindel, varscan2
- CBFA2T2 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60075131; called by muse, mutect2, varscan2
- CBX6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53321698; called by muse, mutect2, varscan2
- CBX8 | c.956dup p.L320Pfs*38 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs752404275; called by mutect2, varscan2
- CBY2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs376455643; called by muse, mutect2, varscan2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC178 | c.1151del p.N384Mfs*13 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs749875431; called by mutect2, pindel, varscan2
- CCDC188 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1335417904; called by muse, varscan2
- CCDC40 | c.3373C>A p.L1125M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV56411068; called by muse, mutect2, varscan2
- CCDC42 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as rs1008726041, COSV53449399; called by muse, mutect2, varscan2
- CCDC61 | c.305dup p.R103Pfs*27 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | catalogued as rs763812164; called by mutect2, pindel, varscan2
- CCDC66 | c.619dup p.T207Nfs*2 (on ENST00000394672 / NM_001353147.1; = p.T173Nfs*2 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 72/235 reads (31%) | catalogued as rs1247408644; called by mutect2, varscan2
- CCER1 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62648192; called by muse, mutect2, varscan2
- CCN6 | c.252A>C p.E84D | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV57890151; called by muse, mutect2, varscan2
- CCP110 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66816515, COSV66817745; called by muse, mutect2, varscan2
- CD207 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV69652488; called by muse, mutect2, varscan2
- CD300LG | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53225186; called by muse, mutect2, varscan2
- CDC42BPB | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV63476362; called by muse, mutect2, varscan2
- CDCP1 | c.1171T>G p.S391A | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56107312; called by muse, mutect2, varscan2
- CDH2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs753588105, COSV52284130; called by muse, mutect2, varscan2
- CDRT1 | c.1427G>C p.S476T | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV55413032; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs763090473; called by mutect2, varscan2
- CEP112 | c.642+1del p.X214_splice | Splice Site (DEL) | VAF 24/261 reads (9%) | catalogued as COSV67143533; called by pindel, varscan2*
- CEP152 | c.3866A>C p.K1289T (on ENST00000380950 / NM_001194998.2; = p.K1233T on NM_014985.4) | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57862924; called by muse, mutect2, varscan2
- CERK | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV53452743; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 34/106 reads (32%) | catalogued as rs768479535; called by mutect2, varscan2
- CFAP100 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367940063; called by muse, mutect2, varscan2
- CFAP69 | c.2061del p.K687Nfs*43 | Frame Shift Del (DEL) | VAF 51/132 reads (39%) | catalogued as rs1275710203; called by mutect2, pindel, varscan2
- CFAP77 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs1451748027, COSV57506583; called by muse, mutect2, varscan2
- CH25H | c.193del p.V65Cfs*32 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as COSV64092559; called by mutect2, pindel, varscan2
- CHAF1B | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs768250753, COSV58441170; called by muse, mutect2, varscan2
- CHD7 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 144/268 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.689); catalogued as rs759887905, COSV71113485; called by muse, mutect2, varscan2
- CHST15 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748902428, COSV60564798; called by muse, mutect2, varscan2
- CKAP5 | c.4735G>A p.G1579S | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs746453148; called by muse, mutect2, varscan2
- CLCA4 | c.236T>G p.L79* | Nonsense Mutation (SNP) | VAF 61/171 reads (36%) | catalogued as rs773085050, COSV55368525; called by muse, mutect2, varscan2
- CLEC11A | c.86G>T p.W29L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV51574782; called by muse, mutect2, varscan2
- CLEC4D | c.599A>T p.N200I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV55230389; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CLSPN | c.3415C>T p.R1139* | Nonsense Mutation (SNP) | VAF 39/127 reads (31%) | catalogued as rs1344308365, COSV52051490; called by muse, mutect2, varscan2
- CLSTN1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363487449; called by muse, mutect2
- CMC2 | c.102dup p.G35Wfs*4 | Frame Shift Ins (INS) | VAF 53/160 reads (33%) | catalogued as rs1269697841; called by mutect2, pindel, varscan2
- CNBD2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs200885142, COSV62586786; called by muse, mutect2, varscan2
- CNOT11 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775090253, COSV56819184; called by muse, mutect2
- CNR1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs199892728, COSV62990502; called by muse, mutect2, varscan2
- CNTNAP2 | c.3650C>T p.S1217L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.288); catalogued as rs1409978017, COSV62232872; called by muse, mutect2, varscan2
- COL7A1 | c.6160G>A p.A2054T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs751691247, COSV60400936; called by muse, mutect2, varscan2
- COLGALT1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53110150; called by muse, mutect2, varscan2
- CORO1C | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV54594022; called by muse, mutect2, varscan2
- COX5B | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs142213285; called by muse, mutect2, varscan2
- CPA5 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as COSV62570461; called by muse, mutect2, varscan2
- CPEB1 | c.1604G>A p.R535H (on ENST00000617958; = p.R470H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55617971, COSV55620745; called by muse, mutect2, varscan2
- CPNE8 | c.787A>G p.N263D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as COSV58849275; called by muse, mutect2, varscan2
- CPOX | c.1075A>G p.R359G | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV51639336; called by muse, mutect2, varscan2
- CRACR2B | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs908199889, COSV58990696; called by muse, mutect2, varscan2
- CRB1 | c.2049C>A p.S683R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV66332533; called by muse, mutect2, varscan2
- CRB3 | c.84A>G p.I28M | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57569378; called by muse, mutect2, varscan2
- CREBBP | c.3493T>C p.W1165R | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52135838; called by muse, mutect2, varscan2
- CROCC2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs770551553; called by muse, mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD3 | c.9823G>T p.G3275W (on ENST00000297405 / NM_001363185.1; = p.G3106W on NM_052900.3) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52276628; called by muse, mutect2, varscan2
- CSMD3 | c.1488G>T p.K496N (on ENST00000297405 / NM_001363185.1; = p.K392N on NM_052900.3) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52276652; called by muse, mutect2, varscan2
- CTNNA3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372758887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.8254G>T p.G2752C | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747786939, COSV64723780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUZD1 | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 72/183 reads (39%) | catalogued as COSV59027633; called by muse, mutect2, varscan2
- CXADR | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs778453029, COSV53030419; called by muse, mutect2, varscan2
- CYP11B2 | c.1486dup p.L496Pfs*8 | Frame Shift Ins (INS) | VAF 20/177 reads (11%) | catalogued as rs1204835904; called by mutect2, pindel, varscan2
- CYP26B1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV50013719; called by muse, mutect2, varscan2
- DAB2IP | c.1844G>A p.R615H (on ENST00000408936; = p.R587H on NM_032552.3) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs774832244; called by muse, mutect2, varscan2
- DAPK1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375598719; called by muse, mutect2, varscan2
- DBN1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52792182; called by muse, mutect2, varscan2
- DBT | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV64496127; called by muse, mutect2, varscan2
- DCC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267605206, COSV59087112; called by muse, mutect2, varscan2
- DCLK3 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV69364289; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DCTN2 | c.599dup p.D201Rfs*2 (on ENST00000548249 / NM_001261413.2; = p.D206Rfs*2 on NM_006400.4) | Frame Shift Ins (INS) | VAF 68/188 reads (36%) | catalogued as rs745744034; called by mutect2, varscan2
- DDX28 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV60106038; called by muse, mutect2, varscan2
- DDX59 | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.905); catalogued as rs755695604, COSV58753458; called by muse, mutect2, varscan2
- DEAF1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs777396337, COSV58608788; called by muse, mutect2, varscan2
- DENND11 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 73/209 reads (35%) | catalogued as rs756544686, COSV72097778; called by muse, mutect2, varscan2
- DENND11 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as rs781700741, COSV72097614; called by muse, mutect2, varscan2
- DIABLO | c.65C>T p.A22V (on ENST00000443649 / NM_001278303.1; = p.A95V on NM_019887.6) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs112610245, COSV57337180; called by muse, mutect2, varscan2
- DIS3L2 | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553539253, COSV56052052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV52307798; called by mutect2, pindel
- DLX4 | c.339del p.A114Pfs*19 (on ENST00000240306 / NM_138281.3; = p.A42Pfs*19 on NM_001934.3) | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as COSV53593194; called by pindel, varscan2
- DMGDH | c.725A>T p.N242I | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV54867465; called by muse, mutect2, varscan2
- DNAAF6 | c.395del p.K132Rfs*11 | Frame Shift Del (DEL) | VAF 39/73 reads (53%) | catalogued as rs1202111757; called by mutect2, pindel, varscan2
- DNAH1 | c.11274C>A p.F3758L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56238832; called by muse, mutect2, varscan2
- DNAH17 | c.11153C>T p.T3718M | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371147513; called by muse, mutect2, varscan2
- DNAH7 | c.1037dup p.Q347Afs*6 | Frame Shift Ins (INS) | VAF 106/349 reads (30%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAL4 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs369970815; called by muse, mutect2, varscan2
- DNMT1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as rs781646588, COSV61582354; ClinVar: uncertain significance; called by muse, varscan2
- DOCK3 | c.627T>G p.C209W | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.639); catalogued as COSV56541383; called by muse, mutect2, varscan2
- DOCK3 | c.3187C>G p.L1063V | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV56541396, COSV99808102; called by muse, mutect2, varscan2
- DPH2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs760454990, COSV52544672; called by muse, mutect2, varscan2
- DPPA5 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV64875412; called by muse, mutect2, varscan2
- DSC2 | c.2398del p.A800Lfs*56 (on ENST00000280904 / NM_024422.6; = p.A800Lfs*45 on NM_004949.5) | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | catalogued as rs397517399; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- DSC2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs978623916, COSV51867895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAML1 | c.5854C>T p.R1952W (on ENST00000321322; = p.R1892W on NM_020693.4) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201027576, COSV58387248; called by muse, mutect2, varscan2
- DSG4 | c.1303A>G p.S435G | Missense Mutation (SNP) | VAF 60/546 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57396023; called by muse, mutect2
- DST | c.15957G>T p.Q5319H (on ENST00000361203 / NM_001374722.1; = p.Q2907H on NM_015548.5) | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV55032987; called by muse, mutect2, varscan2
- DTNA | c.268del p.Y90Tfs*47 | Frame Shift Del (DEL) | VAF 74/253 reads (29%) | catalogued as COSV51997228; called by mutect2, pindel, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs1381179969; called by mutect2, pindel, varscan2
- DUSP16 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs532656810, COSV53808868; called by muse, mutect2, varscan2
- DYNLT1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV65560545; called by muse, mutect2, varscan2
- DYRK3 | c.1605G>T p.K535N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV65607395; called by muse, mutect2, varscan2
- ECEL1 | c.1700del p.P567Hfs*48 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as COSV58813737; called by mutect2, pindel, varscan2
- EFCAB11 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99965648; called by muse, mutect2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs751148694; called by mutect2, varscan2
- ELOA2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV55305421; called by muse, mutect2, varscan2
- EML4 | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59303283; called by muse, mutect2, varscan2
- EMP3 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV53157034, COSV53158381; called by muse, mutect2, varscan2
- EPHA1 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV51974550; called by muse, mutect2, varscan2
- EPHA3 | c.771T>A p.C257* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV60720424; called by muse, mutect2, varscan2
- EPHB1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67668182; called by muse, mutect2, varscan2
- ERCC6 | c.4328G>A p.G1443D | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63393299; called by muse, mutect2, varscan2
- ERP27 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56764386; called by muse, mutect2, varscan2
- EVPL | c.5015G>A p.S1672N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56914541; called by muse, mutect2, varscan2
- EYS | c.7510C>A p.P2504T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs1351717011, COSV65530023; called by muse, mutect2, varscan2
- F2R | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.459); catalogued as COSV59929867; called by muse, mutect2, varscan2
- F2RL2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV56971697, COSV99167787; called by muse, mutect2, varscan2
- FAAP100 | c.1560G>T p.Q520H | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV59886993; called by muse, mutect2, varscan2
- FADS3 | c.1287-2A>G p.X429_splice | Splice Site (SNP) | VAF 30/183 reads (16%) | catalogued as COSV53879901; called by muse, mutect2, varscan2
- FAM110A | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55727931; called by muse, mutect2, varscan2
- FAM110B | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs755553412, COSV64064194; called by muse, mutect2, varscan2
- FAM118A | c.1035dup p.R346Tfs*7 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | catalogued as rs1356118949; called by mutect2, varscan2
- FAM124B | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV66273216; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM151A | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs780576125, COSV56365787; called by muse, mutect2, varscan2
- FAM170B | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1256901590, COSV61253650, COSV61253833, COSV61254012; called by muse, mutect2, varscan2
- FAM171B | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs145285890, COSV59004840; called by muse, mutect2, varscan2
- FAM184A | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs537204974, COSV58857390; called by muse, mutect2, varscan2
- FAM187A | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs1057231536; called by muse, mutect2, varscan2
- FAM216B | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58271145; called by muse, mutect2, varscan2
- FAM53B | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.118); catalogued as rs1253345712, COSV61561264; called by muse, mutect2, varscan2
- FAM83H | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.31); catalogued as COSV66354403; called by muse, mutect2, varscan2
- FANCM | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.264); catalogued as rs139726733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAP | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141855900, COSV51865909; called by muse, mutect2, varscan2
- FARP2 | c.2005G>A p.V669I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749525881, COSV50877738; called by muse, mutect2, varscan2
- FAT1 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71675472; called by muse, mutect2, varscan2
- FBN3 | c.6703G>A p.V2235I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs754675590, COSV54459546; called by muse, mutect2, varscan2
- FBXL15 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50054464; called by muse, mutect2, varscan2
- FBXL18 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV66668086; called by muse, mutect2, varscan2
- FBXL7 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs576303242, COSV61641769; called by muse, mutect2, varscan2
- FBXO11 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs753732511, COSV57024438; called by muse, mutect2, varscan2
- FBXW12 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56485032; called by muse, mutect2
- FCN3 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.118); catalogued as rs749146507; called by muse, mutect2, varscan2
- FER1L5 | c.826G>A p.V276M (on ENST00000623019; = p.V293M on NM_001293083.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV70069771; called by muse, mutect2, varscan2
- FER1L6 | c.1406dup p.E470Gfs*8 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs950533888; called by mutect2, pindel, varscan2
- FES | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61000247; called by muse, mutect2, varscan2
- FGD4 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as rs899737461, COSV56781641; called by muse, mutect2, varscan2
- FGF13 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 80/100 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs1217019171, COSV65440745; called by muse, mutect2, varscan2
- FGFR3 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53413745; called by muse, mutect2, varscan2
- FILIP1 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 136/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52737729; called by muse, mutect2, varscan2
- FILIP1L | c.1637C>T p.A546V (on ENST00000354552 / NM_182909.3; = p.A306V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/470 reads (33%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.589); catalogued as rs373504477; called by muse, mutect2, varscan2
- FILIP1L | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs766701827, COSV58773773; called by muse, mutect2, varscan2
- FLNC | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs777199447, COSV57951286; called by muse, mutect2, varscan2
- FMN2 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs771047438, COSV60445898; called by muse, mutect2, varscan2
- FN1 | c.2303T>C p.L768P | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60560596; called by muse, mutect2, varscan2
- FOCAD | c.2803C>T p.L935F | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV58105635; called by muse, mutect2, varscan2
- FOXK1 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61067960; called by muse, mutect2, varscan2
- FOXM1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV61206588; called by muse, mutect2, varscan2
- FRAS1 | c.4487A>C p.K1496T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV53635768, COSV99347405; called by muse, mutect2, varscan2
- FSTL4 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs1238368967, COSV54781785; called by muse, varscan2
- FTCD | c.1261-8T>C | Splice Region (SNP) | VAF 30/94 reads (32%) | catalogued as COSV52428318; called by muse, mutect2, varscan2
- FTSJ3 | c.2193G>T p.W731C | Missense Mutation (SNP) | VAF 164/415 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63790968; called by muse, mutect2, varscan2
- FUZ | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs779762408, COSV58240912; called by muse, mutect2, varscan2
- G3BP1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs370340219, COSV62366683, COSV62366727; called by muse, mutect2, varscan2
- G6PC2 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV56373176; called by muse, mutect2, varscan2
- GAB4 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68754819; called by muse, mutect2, varscan2
- GAD1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 115/314 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV60153699; called by muse, mutect2, varscan2
- GAL3ST4 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs140660995; called by muse, mutect2, varscan2
- GBF1 | c.1337A>G p.Q446R (on ENST00000369983 / NM_001377137.1; = p.Q445R on NM_004193.3) | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV64147978; called by muse, mutect2, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs768450027; called by mutect2, pindel, varscan2
- GFPT1 | c.28T>C p.Y10H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV61949832; called by muse, mutect2, varscan2
- GFRA2 | c.1190G>C p.S397T | Missense Mutation (SNP) | VAF 116/202 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.3); catalogued as COSV99074223; called by muse, mutect2, varscan2
- GLB1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs553660803, COSV56567000; called by muse, mutect2, varscan2
- GLB1L2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762390001, COSV60280111; called by muse, mutect2, varscan2
- GLG1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764599334, COSV52672363; called by muse, mutect2, varscan2
- GMPS | c.1417del p.S473Lfs*26 | Frame Shift Del (DEL) | VAF 65/210 reads (31%) | catalogued as rs1327172624; called by mutect2, pindel, varscan2
- GNL1 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545644145, COSV64835471; called by muse, mutect2, varscan2
- GNL2 | c.1595A>C p.N532T | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99953711; called by muse, mutect2
- GORASP1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766833329, COSV57188379; called by muse, mutect2, varscan2
- GPLD1 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs759706689, COSV57760028; called by muse, mutect2, varscan2
- GPR152 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as rs897278849, COSV56887712; called by muse, mutect2, varscan2
- GPR20 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753512870, COSV66684450; called by muse, mutect2, varscan2
- GPR87 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.656); catalogued as rs760390826, COSV53463301; called by muse, mutect2, varscan2
- GPRIN1 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV56139310; called by muse, mutect2, varscan2
- GPRIN3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60886091; called by muse, mutect2, varscan2
- GREM2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV58946484; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.2650A>G p.M884V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777297903; called by muse, mutect2, varscan2
- GRIN2B | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs764171423, COSV101663214, COSV74207226; called by muse, mutect2, varscan2
- GRIN2B | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV74205999, COSV74207227; called by muse, mutect2, varscan2
- GRIP2 | c.1366G>A p.V456M (on ENST00000619221; = p.V359M on NM_001080423.4) | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs532400436, COSV56120489; called by muse, mutect2, varscan2
- GRM1 | c.2394G>T p.W798C | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51250700; called by muse, mutect2, varscan2
- GTF3C1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 58/161 reads (36%) | catalogued as COSV55188883; called by muse, mutect2, varscan2
- GYS1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54402926, COSV54404663; called by muse, mutect2, varscan2
- GZF1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57637362; called by muse, mutect2, varscan2
- GZMH | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV53539423; called by muse, mutect2, varscan2
- H4C6 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.08); catalogued as rs1403757246, COSV66685753; called by muse, mutect2, varscan2
- HACE1 | c.1673A>G p.H558R | Missense Mutation (SNP) | VAF 145/454 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV53506132; called by muse, mutect2, varscan2
- HADHA | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204190984, CM994328, COSV66106823; called by muse, mutect2, varscan2
- HBP1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); catalogued as COSV56018968; called by muse, mutect2, varscan2
- HDAC4 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs375565547; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 76/103 reads (74%) | catalogued as COSV100625709; called by mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HDGFL2 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV56684431; called by muse, mutect2, varscan2
- HDLBP | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51472303; called by muse, mutect2, varscan2
- HECTD4 | c.11593G>A p.A3865T | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs746652642, COSV66397361; called by muse, mutect2, varscan2
- HEPHL1 | c.2294G>T p.R765I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59895046; called by muse, mutect2, varscan2
- HHLA2 | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV63319298; called by muse, mutect2, varscan2
- HIC1 | c.1312G>A p.V438M (on ENST00000322941 / NM_001098202.1; = p.V419M on NM_006497.4) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1016949003, COSV53973204; called by muse, mutect2, varscan2
- HLA-DPB1 | c.577del p.Q193Sfs*35 | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | catalogued as rs780393867; called by mutect2, pindel, varscan2
- HLA-DQA2 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as COSV66566428; called by muse, mutect2
- HMCN2 | c.9049G>A p.E3017K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.869); catalogued as rs886494637; called by muse, mutect2, varscan2
- HOOK2 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs372675413; called by muse, mutect2, varscan2
- HOXC9 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749476187, COSV57717164; called by muse, mutect2, varscan2
- HS6ST1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773632691, COSV52127130; called by muse, mutect2
- HSCB | c.333+1G>A p.X111_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as rs1259643683, COSV53262890; called by muse, mutect2, varscan2
- HSPA13 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53466146; called by muse, mutect2, varscan2
- HSPA6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100553814, COSV100553971, COSV59062196; called by muse, mutect2, varscan2
- HTR3C | c.363G>T p.W121C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59176879; called by muse, mutect2, varscan2
- ICE1 | c.2044A>G p.T682A | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV56830072; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IGF2BP1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs1259690630, COSV51734565; called by muse, mutect2, varscan2
- IGF2R | c.5387C>A p.P1796H | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs754279467, COSV63627999; called by muse, mutect2, varscan2
- IGFALS | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs201622145; called by muse, mutect2, varscan2
- IGFBP2 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV52081071; called by muse, mutect2, varscan2
- IGHV2-26 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1555476607; called by muse, varscan2
- IGKV3D-11 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs751162344; called by muse, mutect2, varscan2
- IGLL1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as rs199529532; ClinVar: uncertain significance; called by mutect2, varscan2
- IGSF3 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59596497; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP4A | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293996326, COSV50813949, COSV99305638; called by muse, mutect2, varscan2
- INTS5 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57953037; called by muse, mutect2, varscan2
- IPO9 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | catalogued as COSV64235133; called by muse, mutect2, varscan2
- IQCN | c.703del p.L235Wfs*17 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs748291022, COSV66574173; called by mutect2, pindel
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 47/111 reads (42%) | catalogued as rs771739474; called by mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX1 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.319); catalogued as COSV57361632; called by muse, varscan2
- IRX1 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV57357852, COSV57361641; called by muse, varscan2
- ISLR | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV51434791; called by muse, mutect2, varscan2
- ISM1 | c.579dup p.R194Qfs*14 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs762230866; called by mutect2, varscan2
- ITGAE | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375168971; called by muse, mutect2, varscan2
- ITGB4 | c.5189G>A p.G1730D | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52330896; called by muse, mutect2, varscan2
- ITPKB | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746879876, COSV55265225, COSV55267280; called by muse, mutect2, varscan2
- ITPKB | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 39/68 reads (57%) | catalogued as COSV55259328; called by muse, varscan2
- ITPR3 | c.7570C>T p.R2524C | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267690; called by muse, mutect2, varscan2
- ITSN2 | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs755592783, COSV61952244; called by muse, mutect2, varscan2
- IZUMO1 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV55807338; called by muse, mutect2, varscan2
- JPH3 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52472365; called by muse, mutect2, varscan2
- KANSL3 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV62621273; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs1159900432; called by mutect2, pindel, varscan2
- KCNG2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756656712, COSV60267153; called by muse, mutect2, varscan2
- KCNH4 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1324370058, COSV52920276; called by muse, mutect2, varscan2
- KCNK17 | c.503del p.G168Afs*61 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as COSV64685346; called by mutect2, pindel, varscan2
- KCNS1 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60260725; called by muse, mutect2, varscan2
- KCNS1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV60260735; called by muse, mutect2, varscan2
- KCNT1 | c.3181G>T p.G1061C (on ENST00000488444; = p.G1087C on NM_020822.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV53708109; called by muse, mutect2, varscan2
- KCNT2 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 227/602 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV54100460; called by muse, mutect2, varscan2
- KDM4B | c.1375T>G p.F459V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV50245555; called by muse, mutect2, varscan2
- KDM6A | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 282/389 reads (72%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1322780338, COSV65043950; called by muse, mutect2, varscan2
- KDM6B | c.3245C>T p.P1082L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs762371888, COSV54683310; called by muse, mutect2, varscan2
- KHSRP | c.2095del p.Q699Sfs*24 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1481620263, COSV67919982; called by mutect2, pindel, varscan2
- KIF13B | c.4669C>T p.P1557S | Missense Mutation (SNP) | VAF 106/176 reads (60%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.998); catalogued as rs1428654026, COSV68094592; called by mutect2, varscan2
- KIF15 | c.668del p.R223Lfs*7 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as COSV58163868; called by mutect2, pindel, varscan2
- KIF1A | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as rs1049441176, COSV57498002; called by muse, mutect2, varscan2
- KIF24 | c.1982dup p.P662Afs*10 | Frame Shift Ins (INS) | VAF 30/109 reads (28%) | catalogued as rs570788521; called by mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 66/178 reads (37%) | catalogued as rs771825279; called by mutect2, varscan2
- KIF26A | c.3805del p.R1269Gfs*7 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs1458694083, COSV59464465; called by mutect2, pindel, varscan2
- KIF26B | c.3818G>T p.S1273I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63640492, COSV63648571; called by muse, mutect2, varscan2
- KIF2C | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64765401; called by muse, mutect2, varscan2
- KIF3A | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 66/197 reads (34%) | catalogued as rs1188869657, COSV66415585; called by muse, mutect2, varscan2
- KIFAP3 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV63036170; called by muse, mutect2, varscan2
- KIRREL2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52879086; called by muse, mutect2, varscan2
- KLF1 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1388363360, COSV53435797; called by muse, mutect2, varscan2
- KLHDC7B | c.754C>T p.R252* (on ENST00000395676; = p.R893* on NM_138433.5) | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV67465115; called by muse, mutect2, varscan2
- KLHDC7B | c.1504C>T p.R502W (on ENST00000395676; = p.R1143W on NM_138433.5) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758075611, COSV67464366; called by muse, mutect2, varscan2
- KLHL12 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.488); catalogued as COSV66127840; called by muse, mutect2, varscan2
- KMT2B | c.6994C>T p.R2332C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs759167832, COSV55858250; called by muse, mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as COSV54178849; called by mutect2, varscan2
- KRT7 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV59332502; called by muse, mutect2, varscan2
- KRTAP5-8 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101273178, COSV68324821; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs750491454; called by mutect2, varscan2
- KSR2 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as CM1311363, COSV56673915; called by muse, mutect2, varscan2
- KTN1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.105); catalogued as rs776818967, COSV68025038; called by muse, mutect2, varscan2
- L3MBTL1 | c.2311G>A p.A771T (on ENST00000418998 / NM_001377303.1; = p.A681T on NM_015478.7) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs868489823, COSV64229364; called by muse, mutect2, varscan2
- LAMA5 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs371375888; called by muse, mutect2, varscan2
- LARP4B | c.1550C>A p.P517Q | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60223021; called by muse, mutect2, varscan2
- LARP4B | c.193del p.A65Lfs*15 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as rs1564415815; called by mutect2, pindel, varscan2
- LCE2C | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.414); catalogued as COSV64228286, COSV64228626; called by muse, mutect2, varscan2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, mutect2, varscan2
- LCT | c.4750G>T p.D1584Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51555227; called by muse, mutect2, varscan2
- LDB1 | c.604C>T p.R202W (on ENST00000425280 / NM_001321612.2; = p.R166W on NM_003893.5) | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919693683, COSV63289783; called by muse, mutect2, varscan2
- LDB2 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs138614817; called by muse, mutect2, varscan2
- LDHD | c.1280T>C p.F427S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55581710; called by muse, mutect2, varscan2
- LEPR | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 140/378 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369281071; called by muse, varscan2
- LFNG | c.520C>T p.R174C (on ENST00000222725 / NM_001040167.2; = p.R45C on NM_002304.2) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373426024; called by muse, mutect2, varscan2
- LHFPL3 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs376545400; called by muse, varscan2
- LILRA5 | c.712G>T p.G238* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as COSV56644629; called by muse, mutect2, varscan2
- LINGO2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs1329891686, COSV58061180; called by muse, mutect2, varscan2
- LMBR1L | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs764745912, COSV57267091; called by muse, mutect2, varscan2
- LMBRD2 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 38/479 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV56951906; called by muse, mutect2
- LMF1 | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1047361482, COSV51900914; called by muse, mutect2, varscan2
- LMO3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53781944, COSV53784522; called by muse, varscan2
- LPA | c.5469del p.C1824Vfs*27 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | catalogued as rs752960449; called by mutect2, pindel, varscan2
- LPCAT4 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100149130, COSV59218342; called by muse, mutect2, varscan2
- LRFN2 | c.1987C>A p.L663M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV57832576; called by muse, mutect2, varscan2
- LRP1B | c.11797G>A p.D3933N | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67279747; called by muse, varscan2
- LRP2 | c.3859G>A p.A1287T | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV55567855; called by muse, mutect2, varscan2
- LRRC37A2 | c.3858G>T p.K1286N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61004108; called by muse, mutect2, varscan2
- LRRC8C | c.1524dup p.W509Lfs*20 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | catalogued as rs762972819; called by mutect2, varscan2
- LRRFIP2 | c.412T>G p.S138A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60869517; called by muse, mutect2, varscan2
- LRRK2 | c.6694G>T p.G2232W | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV54165041; called by muse, mutect2, varscan2
- LRRTM1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54439470, COSV54445260; called by muse, mutect2, varscan2
- LSS | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764497439; called by muse, mutect2, varscan2
- LTBP2 | c.1756del p.V586* | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs776807257; called by mutect2, pindel, varscan2
- LTBP3 | c.3767A>T p.D1256V (on ENST00000301873 / NM_001130144.3; = p.D1209V on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214685; called by muse, mutect2, varscan2
- LTBR | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57439703; called by muse, mutect2, varscan2
- LYZL1 | c.567del p.G190Afs*19 (on ENST00000375500; = p.G144Afs*19 on NM_032517.6) | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as rs1376851399, COSV64966279; called by mutect2, pindel, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAP3K11 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.013); catalogued as rs763348971; called by muse, mutect2, varscan2
- MAP7 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1479705735, COSV63422122; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306450018, COSV51599872; called by muse, mutect2, varscan2
- MAPT | c.2312G>A p.R771H (on ENST00000262410 / NM_001377265.1; = p.R379H on NM_005910.5) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1568347450, COSV52240871; called by muse, mutect2, varscan2
- MARCO | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59053024, COSV59057163; called by muse, varscan2
- MARCO | c.1483C>A p.L495M | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59057173, COSV59057716; called by muse, mutect2, varscan2
- MARF1 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV60023856; called by muse, mutect2, varscan2
- MBD1 | c.1037G>A p.R346Q (on ENST00000269468 / NM_001323950.1; = p.R323Q on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1157454060, COSV54005577; called by muse, mutect2, varscan2
- MBL2 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs769868112, COSV64759182; called by muse, mutect2, varscan2
- MCF2L | c.578C>T p.P193L (on ENST00000375608; = p.P161L on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750060795, COSV65052367; called by muse, mutect2, varscan2
- MCF2L2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs773032244, COSV61055281; called by muse, mutect2, varscan2
- MCM10 | c.1888C>T p.R630* (on ENST00000484800 / NM_182751.3; = p.R629* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as rs148160347; called by muse, mutect2, varscan2
- MCRS1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1399363782, COSV59460979; called by muse, mutect2, varscan2
- MCTP1 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs144106740; called by muse, mutect2, varscan2
- ME1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs768184237, COSV63838527; called by muse, mutect2, varscan2
- MEGF8 | c.3266C>T p.A1089V (on ENST00000251268 / NM_001271938.2; = p.A1022V on NM_001410.3) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749389938; called by muse, mutect2, varscan2
- MEGF8 | c.4213G>A p.A1405T (on ENST00000251268 / NM_001271938.2; = p.A1338T on NM_001410.3) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.48); catalogued as COSV52097021; called by muse, mutect2, varscan2
- MEPCE | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1430244677, COSV52769750; called by muse, mutect2, varscan2
- MFSD2A | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.228); catalogued as COSV65686329; called by muse, mutect2, varscan2
- MFSD6L | c.1163T>A p.F388Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61004945; called by muse, mutect2, varscan2
- MIB1 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55093613; called by muse, mutect2, varscan2
- MICALL2 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514338; called by muse, mutect2
- MKX | c.189C>T p.G63= | Splice Region (SNP) | VAF 24/35 reads (69%) | catalogued as COSV65392946; called by muse, varscan2
- MLLT10 | c.1825G>A p.A609T (on ENST00000307729 / NM_001195626.3; = p.A625T on NM_004641.3) | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1368852605, COSV56993099, COSV57001972; called by muse, mutect2
- MMP12 | c.318del p.V108Yfs*18 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as rs782219122; called by mutect2, pindel, varscan2
- MMP15 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757069983, COSV54681098; called by muse, mutect2, varscan2
- MORC4 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1366297708, COSV55242913; called by muse, mutect2, varscan2
- MORC4 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV55245506; called by muse, mutect2, varscan2
- MRGPRG | c.535del p.V179Wfs*7 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV60040777; called by mutect2, pindel, varscan2
- MS4A8 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs758725009, COSV55753158; called by muse, mutect2, varscan2
- MSRB1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs748260206; called by muse, mutect2, varscan2
- MSS51 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1282642290, COSV55020359; called by muse, mutect2, varscan2
- MTCL1 | c.1846G>A p.A616T (on ENST00000306329 / NM_001378206.1; = p.A256T on NM_015210.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757292748, COSV60403859; called by muse, mutect2, varscan2
- MUC16 | c.40193G>A p.R13398H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.369); catalogued as rs764581423, COSV66689492; called by muse, mutect2, varscan2
- MUC16 | c.19967C>A p.A6656D | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); catalogued as COSV67483964; called by muse, mutect2, varscan2
- MUC17 | c.6003G>T p.E2001D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV60299069; called by muse, mutect2, varscan2
- MUC4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.494); catalogued as rs1438580385; called by muse, varscan2
- MYB | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV57200732; called by muse, mutect2, varscan2
- MYCBP2 | c.11968G>A p.V3990I (on ENST00000357337; = p.V4028I on NM_015057.5) | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62011373; called by muse, mutect2, varscan2
- MYCN | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.527); catalogued as COSV55260499; called by muse, mutect2, varscan2
- MYH9 | c.5089C>T p.R1697C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372871106; called by muse, mutect2, varscan2
- MYLK | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as rs756465340, CM158371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO5A | c.5191C>T p.R1731C | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369584772, COSV100698123; called by muse, mutect2, varscan2
- MYO5B | c.4070A>T p.E1357V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV53227497; called by muse, mutect2, varscan2
- MYO5C | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 61/162 reads (38%) | catalogued as rs757155615, COSV55902427; called by muse, mutect2, varscan2
- MYO7B | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270888100, COSV67348560; called by muse, mutect2, varscan2
- MYOM1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.288); catalogued as rs866304969, COSV55298524; called by muse, mutect2, varscan2
- MYRIP | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs1317250226, COSV56878039; called by muse, mutect2, varscan2
- MYT1L | c.504C>T p.N168= | Splice Region (SNP) | VAF 29/71 reads (41%) | catalogued as rs758684369, COSV67720555; called by muse, mutect2, varscan2
- NAA38 | c.81G>T p.G27= (on ENST00000575771 / NM_001320925.2; = p.G14V on NM_032356.5) | Splice Region (SNP) | VAF 49/129 reads (38%) | catalogued as rs1391769681, COSV54685204; called by muse, mutect2, varscan2
- NACAD | c.639del p.A214Pfs*92 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs1258262322; called by mutect2, pindel, varscan2
- NAV2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs765091913, COSV62330786; called by muse, mutect2, varscan2
- NCCRP1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59212966; called by muse, mutect2, varscan2
- NCDN | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs1203753278; called by muse, mutect2, varscan2
- NCOA1 | c.1948A>G p.I650V | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1306868407, COSV56050777; called by muse, mutect2, varscan2
- NCOA2 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs767352400, COSV51219332; called by muse, mutect2, varscan2
- NDEL1 | c.701-1G>A p.X234_splice | Splice Site (SNP) | VAF 54/184 reads (29%) | catalogued as COSV55329890; called by muse, mutect2, varscan2
- NDUFA4L2 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100197319; called by muse, mutect2
- NDUFB10 | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51910793; called by muse, mutect2, varscan2
- NECTIN3 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.047); catalogued as COSV100162629; called by muse, mutect2
- NEDD9 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV65222831; called by muse, mutect2, varscan2
- NEFM | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV55334238; called by muse, mutect2, varscan2
- NEFM | c.2581dup p.I861Nfs*4 | Frame Shift Ins (INS) | VAF 29/108 reads (27%) | catalogued as rs1563243996; called by mutect2, pindel, varscan2
- NELL1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1199157497, COSV54290404, COSV54327653; called by muse, mutect2, varscan2
- NELL2 | c.2062del p.C688Afs*90 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs34674438; called by mutect2, pindel, varscan2
- NEO1 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV56076525; called by muse, mutect2, varscan2
- NEURL2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV51944106; called by muse, mutect2, varscan2
- NFATC3 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as rs772345934, COSV60477858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFIB | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV66627696; called by muse, mutect2, varscan2
- NGEF | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.637); catalogued as COSV50942298; called by muse, mutect2, varscan2
- NKD2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.66); catalogued as rs1418786317, COSV56894267; called by muse, mutect2, varscan2
- NKX2-2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65820171; called by muse, mutect2, varscan2
- NKX6-3 | c.646G>T p.G216C (on ENST00000518699 / NM_001364841.2; = p.G86C on NM_152568.3) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV72895185; called by muse, mutect2, varscan2
- NLRC3 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs778330894, COSV57094298; called by muse, mutect2, varscan2
- NLRC5 | c.3936G>T p.Q1312H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV52660778; called by muse, mutect2, varscan2
- NLRP9 | c.791dup p.M265Dfs*36 | Frame Shift Ins (INS) | VAF 38/106 reads (36%) | catalogued as rs745704129; called by mutect2, varscan2
- NMUR2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs768254421, COSV54921636; called by muse, mutect2, varscan2
- NOL4L | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1460119422, COSV62889252; called by muse, mutect2, varscan2
- NOS2 | c.1948del p.A650Pfs*53 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as COSV100569807, COSV58222947; called by mutect2, pindel, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NPC1L1 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs141973731, CM068041; called by muse, mutect2, varscan2
- NR1I2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV61979836; called by muse, mutect2
- NRF1 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1213386958, COSV56210188; called by muse, mutect2, varscan2
- NRG2 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV56838362; called by muse, mutect2, varscan2
- NRG3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64575624; called by muse, mutect2, varscan2
- NRXN1 | c.4228G>A p.A1410T | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs764870690, COSV60515075; called by muse, varscan2
- NRXN1 | c.3825G>T p.L1275F | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768790347; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 94/304 reads (31%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTN1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs762421437, COSV51486351; called by muse, mutect2, varscan2
- NUDT17 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs781948166, COSV57908233; called by muse, mutect2, varscan2
- NUGGC | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58437943; called by muse, mutect2
- NUP205 | c.3779G>A p.S1260N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs764790202, COSV53664240; called by muse, mutect2, varscan2
- NYAP1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.08); catalogued as rs750370682, COSV55717978; called by muse, mutect2, varscan2
- OBSCN | c.14782C>T p.R4928* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as rs758907604, COSV52783018; called by muse, mutect2, varscan2
- OCA2 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374415755, COSV62342124; called by muse, mutect2, varscan2
- OLFML2A | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56581687; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR12D2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs1229980362, COSV65829635; called by muse, mutect2
- OR1E2 | c.312_314del p.F104del | In Frame Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs767081414; called by pindel, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as COSV57137289; called by mutect2, pindel, varscan2
- OR4M1 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 22/491 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV60062971; called by muse, mutect2
- OR5C1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs147276457; called by muse, mutect2, varscan2
- OR5D18 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 157/419 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV61738236, COSV61738342; called by muse, mutect2, varscan2
- OR9Q2 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV61112530; called by muse, mutect2, varscan2
- OTOF | c.2783G>A p.G928D (on ENST00000272371 / NM_194248.3; = p.G181D on NM_004802.4) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV55514302; called by muse, mutect2, varscan2
- OTOP3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.974); catalogued as rs117354589, COSV60914479; called by muse, mutect2, varscan2
- OTULIN | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506572; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- OVCA2 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV53985993; called by muse, mutect2, varscan2
- P3H3 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs372168236, COSV99301088; called by muse, mutect2
- P3H3 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1048589361; called by muse, mutect2, varscan2
- PAQR5 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as rs770284774, COSV61818642; called by muse, mutect2, varscan2
- PASK | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs914190062; called by muse, mutect2, varscan2
- PAXBP1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 246/331 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV51609417; called by muse, varscan2
- PCDH1 | c.3329C>A p.P1110H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV54618056; called by muse, mutect2, varscan2
- PCDH11Y | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs771015976, COSV53088376; called by muse, mutect2, varscan2
- PCDH15 | c.4640G>T p.R1547I | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as COSV100905160, COSV64722175; called by muse, mutect2
- PCDH17 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV64973878; called by muse, mutect2, varscan2
- PCDH7 | c.2384C>A p.A795E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1298790860; called by muse, mutect2, varscan2
- PCDH8 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751594263, COSV100131599, COSV58810615; called by muse, mutect2, varscan2
- PCDHA10 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 124/271 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1554150713, COSV56534395; called by muse, mutect2, varscan2
- PCDHB1 | c.2352del p.E786Rfs*2 | Frame Shift Del (DEL) | VAF 60/180 reads (33%) | catalogued as COSV60632689; called by mutect2, pindel, varscan2
- PCDHB9 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1186232513; called by muse, mutect2
- PCDHGA1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as rs376949512, COSV65298412; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA11 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754599902, COSV54005887; called by muse, mutect2, varscan2
- PCDHGB6 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs760802690, COSV53944105; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCLO | c.10126G>A p.V3376I | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs755305348, COSV61628583; called by muse, varscan2
- PDE4B | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58489985; called by muse, varscan2
- PDP1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52603298; called by muse, mutect2, varscan2
- PDPR | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 146/592 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748974983, COSV55355201; called by muse, mutect2, varscan2
- PDZD8 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs975930351, COSV57827760; called by muse, mutect2, varscan2
- PDZK1 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1553702328; called by muse, mutect2, varscan2
- PEDS1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs199724655; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel
- PFDN1 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 274/709 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs763185306, COSV55837803; called by muse, mutect2, varscan2
- PFKL | c.437_438del p.S146* | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as COSV62464969; called by mutect2, pindel, varscan2
- PGBD2 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs746456938, COSV61400298; called by muse, mutect2, varscan2
- PHACTR1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs377093681; called by muse, mutect2, varscan2
- PHIP | c.2105A>T p.H702L | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV51508471; called by muse, mutect2, varscan2
- PICALM | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1464994938, COSV62673022; called by muse, mutect2, varscan2
- PIGT | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs1353796312, COSV99649037; called by muse, mutect2, varscan2
- PIGV | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777251503, COSV50299909; called by muse, mutect2, varscan2
- PIK3C2A | c.3610G>T p.G1204* | Nonsense Mutation (SNP) | VAF 96/265 reads (36%) | catalogued as COSV56405676; called by muse, mutect2, varscan2
- PIK3C2B | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV65803579, COSV65804043; called by muse, mutect2, varscan2
- PIK3CD | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV63130881; called by muse, mutect2, varscan2
- PIK3IP1 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53224283; called by muse, mutect2, varscan2
- PKD1 | c.10747G>A p.G3583S (on ENST00000262304 / NM_001009944.3; = p.G3582S on NM_000296.4) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51922646; called by muse, mutect2, varscan2
- PKD1L1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs143510449, COSV56974412; called by muse, mutect2, varscan2
- PKD2L1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs1295646926, COSV58395258, COSV58398052; called by muse, mutect2, varscan2
- PKHD1 | c.5399G>A p.C1800Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407690306, COSV61890015; called by muse, mutect2, varscan2
- PKN1 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54401904; called by muse, mutect2, varscan2
- PLAAT2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55374621, COSV55375456; called by muse, mutect2, varscan2
- PLB1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59832996; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 20/69 reads (29%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHF1 | c.244del p.L82Wfs*20 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as COSV101460749; called by mutect2, pindel, varscan2
- PLEKHH3 | c.2283_2285del p.P762del | In Frame Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1267820509; called by pindel, varscan2
- PLEKHM1 | c.3124del p.R1042Afs*24 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV51818060, COSV51818456; called by mutect2, pindel, varscan2
- PLXNB3 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 115/151 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782351638, COSV62795378; called by muse, mutect2, varscan2
- PLXND1 | c.5377G>A p.A1793T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60715390; called by muse, mutect2, varscan2
- PNMT | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54093798, COSV99510477; called by muse, mutect2, varscan2
- POFUT1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279139950, COSV55788982; called by muse, varscan2
- POFUT1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55789386; called by muse, varscan2
- POGZ | c.3695G>A p.R1232H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.543); catalogued as COSV51851192; called by muse, mutect2, varscan2
- POLA1 | c.4061G>A p.R1354H | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.271); catalogued as rs780353506, COSV66887146; called by muse, mutect2, varscan2
- POLE2 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as COSV53561368; called by muse, mutect2, varscan2
- POLQ | c.2260T>G p.S754A | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV51758729; called by muse, varscan2
- POTED | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 207/308 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564938629, COSV55046589; called by muse, mutect2, varscan2
- POTEE | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 139/497 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs557083202, COSV58239685; called by muse, mutect2, varscan2
- POTEJ | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.165); catalogued as rs541088594; called by muse, mutect2, varscan2
- PPFIA3 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV61953929; called by muse, mutect2, varscan2
- PPM1B | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV56768909; called by muse, mutect2, varscan2
- PPM1E | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.257); catalogued as COSV57578307, COSV57578808; called by muse, varscan2
- PPP1R2 | c.410del p.K137Sfs*6 | Frame Shift Del (DEL) | VAF 97/333 reads (29%) | catalogued as rs1295501552; called by mutect2, pindel, varscan2
- PPP1R32 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141041531; called by muse, mutect2, varscan2
- PPP2CB | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 198/344 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV55329619; called by muse, mutect2, varscan2
- PPP2R1A | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1348762266, COSV59042582; called by muse, mutect2, varscan2
- PPP2R2C | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV58675125; called by muse, mutect2, varscan2
- PPP4R3A | c.2417A>G p.Y806C (on ENST00000554943 / NM_001366432.1; = p.Y793C on NM_001284280.1) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61506019; called by muse, mutect2
- PRAMEF17 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 121/377 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as rs1270018952; called by muse, mutect2, varscan2
- PRB2 | c.863del p.P288Hfs*143 | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | catalogued as rs769959335; called by mutect2, pindel, varscan2
- PRDM1 | c.51del p.K18Sfs*7 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs1487333791; called by mutect2, pindel, varscan2
- PRDM15 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770791649, COSV54149666; called by muse, mutect2, varscan2
- PREX1 | c.4810C>T p.R1604W | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447178153, COSV64249860; called by muse, mutect2, varscan2
- PREX2 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV55793015; called by muse, mutect2, varscan2
- PRG4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs142813803; called by muse, mutect2, varscan2
- PRH2 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV67171825; called by muse, mutect2, varscan2
- PRKACG | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768219024, COSV55255040; called by muse, mutect2, varscan2
- PRKCI | c.1375T>C p.S459P | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV55521641; called by muse, mutect2, varscan2
- PRMT2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170385214; called by muse, mutect2, varscan2
- PRR12 | c.1418G>A p.R473H (on ENST00000615927; = p.R1294H on NM_020719.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1166432435, COSV69816922; called by muse, mutect2, varscan2
- PRSS21 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs894960562, COSV50051974; called by muse, mutect2, varscan2
- PRSS53 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs769552498, COSV54926015; called by muse, mutect2, varscan2
- PSAP | c.430del p.H144Tfs*2 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as COSV67551011; called by mutect2, pindel, varscan2
- PSD | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV50042517; called by muse, mutect2, varscan2
- PSD4 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1402019578, COSV55529181; called by muse, mutect2, varscan2
- PSTPIP1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1015646449, COSV51205847; called by muse, mutect2, varscan2
- PTGFRN | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV67799312; called by muse, mutect2, varscan2
- PTGIR | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as rs200825547, COSV52193240; called by muse, mutect2, varscan2
- PTH1R | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs200304786, COSV57317224; called by muse, mutect2, varscan2
- PTP4A3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs776517948, COSV61471165; called by muse, mutect2, varscan2
- PTPN3 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1249778129, COSV52706542; called by muse, mutect2, varscan2
- PTPRN2 | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.184); catalogued as rs369227370; called by muse, mutect2, varscan2
- PTPRS | c.5696G>A p.R1899Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752031088, COSV53632013; called by muse, mutect2, varscan2
- PTX4 | c.1191dup p.G398Rfs*? (on ENST00000447419 / NM_001328608.2; = p.G393Rfs*? on NM_001013658.1) | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs772722517; called by mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- PXN | c.1560G>T p.Q520H (on ENST00000228307 / NM_001080855.3; = p.Q486H on NM_002859.4) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV57220998; called by muse, mutect2, varscan2
- PYGO2 | c.405del p.F136Sfs*25 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV100868881; called by mutect2, pindel, varscan2
- QARS1 | c.516+6C>T | Splice Region (SNP) | VAF 49/133 reads (37%) | catalogued as rs779456780; called by muse, mutect2, varscan2
- RAB35 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57568235, COSV99984480; called by muse, mutect2, varscan2
- RAB40AL | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 108/173 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1294860061, COSV54434988, COSV54435453; called by muse, mutect2, varscan2
- RABEP2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs758567963, COSV62870421, COSV62870594; called by muse, mutect2, varscan2
- RAD54L | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.029); catalogued as rs1380048932; called by muse, mutect2, varscan2
- RALGDS | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1026856324, COSV64429111; called by muse, mutect2, varscan2
- RAPGEF1 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.779); catalogued as COSV64701453; called by muse, mutect2, varscan2
- RAPH1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); catalogued as rs759568749, COSV57356162; called by muse, mutect2, varscan2
- RASAL1 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as COSV55656158; called by muse, mutect2, varscan2
- RBM42 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52898342; called by muse, mutect2, varscan2
- RBMXL3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs1244149161, COSV57757301; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 100/388 reads (26%) | catalogued as COSV100563010; called by pindel, varscan2
- RET | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs371731991, COSV60704091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFC1 | c.2171G>A p.G724D (on ENST00000381897 / NM_001363496.2; = p.G723D on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62898996, COSV62900641; called by muse, mutect2, varscan2
- RGL4 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51945073; called by muse, mutect2, varscan2
- RHOT2 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs760337896, COSV53468004; called by muse, mutect2, varscan2
- RNF133 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 159/487 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769564195, COSV57379158; called by muse, mutect2, varscan2
- RNF213 | c.9590A>C p.K3197T | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.433); catalogued as COSV60405843; called by muse, mutect2, varscan2
- RNF40 | c.2722G>A p.A908T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV100222273; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 57/84 reads (68%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1045339363, COSV71392720, COSV71397929; called by muse, mutect2, varscan2
- RP1 | c.4417A>T p.N1473Y | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV55123732; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/31 reads (52%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL26 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs932068728, COSV99549537; called by muse, mutect2
- RPS6KA4 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1565074849, COSV53702116; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by mutect2, varscan2
- RSPO4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369687640; called by muse, mutect2, varscan2
- RTBDN | c.392C>A p.T131N (on ENST00000393233 / NM_001270444.1; = p.T163N on NM_031429.2) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59806979; called by muse, mutect2, varscan2
- RYR1 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757261781, COSV62106653; called by muse, mutect2, varscan2
- RYR1 | c.5545C>T p.L1849= | Splice Region (SNP) | VAF 4/17 reads (24%) | catalogued as COSV62103555; called by muse, mutect2, varscan2
- RYR1 | c.9848G>A p.R3283Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.574); catalogued as rs757753317; called by muse, mutect2, varscan2
- RYR2 | c.3478G>A p.D1160N | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1064794172, COSV63683718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.4429C>T p.H1477Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV63705212; called by muse, mutect2, varscan2
- RYR2 | c.8830G>A p.D2944N | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV63705217; called by muse, mutect2, varscan2
- SBF1 | c.3228dup p.S1077Qfs*11 | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | catalogued as rs771002611; called by mutect2, varscan2
- SCN2A | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51851754; called by muse, mutect2, varscan2
- SCYL3 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63047348, COSV63048051; called by muse, mutect2, varscan2
- SEC24A | c.974C>G p.T325S | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV59749029; called by muse, mutect2, varscan2
- SEMA4B | c.2384dup p.S797Vfs*6 | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | catalogued as rs759756102; called by mutect2, pindel, varscan2
- SEMA4C | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759619456, COSV59691884; called by muse, mutect2, varscan2
- SEMA4G | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1392930732, COSV52966779, COSV52970912; called by muse, mutect2, varscan2
- SEMA6D | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV60381955; called by muse, mutect2, varscan2
- SEMA7A | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56091153; called by muse, mutect2, varscan2
- SEMG2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV65647813; called by muse, mutect2, varscan2
- SERPINA7 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 80/101 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1470726235; called by muse, mutect2, varscan2
- SERPINB2 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.588); catalogued as COSV55094124; called by muse, mutect2, varscan2
- SETBP1 | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56332706; called by muse, mutect2, varscan2
- SETD1B | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57348462, COSV57353251; called by muse, mutect2, varscan2
- SEZ6 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as COSV57983791; called by muse, mutect2, varscan2
- SF1 | c.1718T>G p.V573G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.208); catalogued as COSV99918660; called by muse, mutect2, varscan2
- SF3B4 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1553765622, COSV54966510; called by muse, mutect2, varscan2
- SFI1 | c.1750C>T p.R584W (on ENST00000400288 / NM_001007467.3; = p.R553W on NM_014775.4) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as rs752234090, COSV101191872; called by muse, mutect2, varscan2
- SFMBT2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251850601, COSV62806679, COSV62813901; called by muse, mutect2, varscan2
- SGK1 | c.1039-1G>C p.X347_splice | Splice Site (SNP) | VAF 39/98 reads (40%) | catalogued as COSV52813673; called by muse, mutect2, varscan2
- SGSM3 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs754704832, COSV50654264; called by muse, mutect2, varscan2
- SHANK3 | c.5101G>A p.V1701M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV53189931; called by muse, mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as COSV53462966; called by mutect2, pindel, varscan2
- SHISA5 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs751472414, COSV56496937; called by muse, mutect2, varscan2
- SHROOM3 | c.4877G>A p.G1626E | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV56036840; called by muse, mutect2, varscan2
- SHROOM4 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 92/121 reads (76%) | SIFT tolerated (0.91); PolyPhen benign (0.019); catalogued as COSV56795049, COSV99173015; called by muse, mutect2, varscan2
- SLC10A1 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV53683535; called by muse, mutect2, varscan2
- SLC12A4 | c.2762A>G p.Y921C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV50454292; called by muse, mutect2, varscan2
- SLC14A1 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1037329168, COSV58933749; called by muse, mutect2, varscan2
- SLC18A3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs981399429, COSV60322347; called by muse, mutect2
- SLC24A2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs746342226, COSV99036438; called by muse, varscan2
- SLC24A2 | c.189T>A p.D63E | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53872203; called by muse, mutect2, varscan2
- SLC25A52 | c.404C>T p.A135V (on ENST00000672005; = p.A125V on NM_001034172.4) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52503769; called by mutect2, varscan2
- SLC34A1 | c.1836del p.R613Gfs*69 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs1418718522; called by mutect2, pindel, varscan2
- SLC34A2 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 52/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV65942713; called by muse, mutect2
- SLC37A1 | c.48G>T p.R16S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV61403931; called by muse, mutect2, varscan2
- SLC38A10 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs779022033, COSV55845938; called by muse, mutect2, varscan2
- SLC39A4 | c.1754G>T p.S585I (on ENST00000301305 / NM_001374839.1; = p.S560I on NM_017767.3) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV52780732; called by muse, mutect2, varscan2
- SLC41A1 | c.938G>T p.R313M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV65651130; called by muse, mutect2, varscan2
- SLC44A4 | c.1853del p.F618Sfs*25 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | catalogued as rs910422495; called by mutect2, varscan2
- SLC7A2 | c.1395G>T p.Q465H (on ENST00000494857 / NM_001370338.1; = p.Q504H on NM_003046.6) | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV50267087; called by muse, mutect2, varscan2
- SLC7A7 | c.1270T>G p.F424V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1403110473, COSV53537969; called by muse, mutect2, varscan2
- SLC7A9 | c.1309T>C p.Y437H | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50082858; called by muse, mutect2, varscan2
- SLC9A4 | c.2213G>A p.G738D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs886960279, COSV54837627; called by muse, mutect2, varscan2
- SLIT2 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as rs755144502, COSV56588418; called by muse, mutect2, varscan2
- SMC2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as rs760941119, COSV53959768; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs1257129093; called by mutect2, pindel
- SMTNL2 | c.1235T>G p.F412C (on ENST00000389313 / NM_001114974.2; = p.F268C on NM_198501.3) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58809418; called by muse, mutect2, varscan2
- SNCAIP | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV54418108; called by muse, mutect2, varscan2
- SNRPB2 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 151/448 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55719614; called by muse, mutect2, varscan2
- SNX2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV65348856; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX29 | c.2276G>T p.S759I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs1204437481, COSV60067692; called by muse, mutect2, varscan2
- SP2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65064870; called by muse, mutect2, varscan2
- SPATA9 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs759120942, COSV57224864; called by muse, mutect2, varscan2
- SPON1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs782464048, COSV100116479; called by muse, mutect2, varscan2
- SPPL2C | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as rs1296305858, COSV61292603; called by muse, mutect2, varscan2
- SPRED2 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62693996; called by muse, mutect2, varscan2
- SPTA1 | c.6049T>G p.W2017G | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63757526; called by muse, mutect2, varscan2
- SPTB | c.4883G>T p.R1628L | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs755882611, COSV67634201, COSV67634258; called by muse, mutect2, varscan2
- SPTBN1 | c.5582G>T p.R1861M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV61692310; called by muse, mutect2, varscan2
- SREBF1 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55418809; called by muse, mutect2, varscan2
- SREBF2 | c.2872G>A p.V958I | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs370413839; called by muse, mutect2, varscan2
- SRPRB | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs141286101; called by muse, mutect2, varscan2
- SRRM2 | c.7451C>T p.T2484M | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs756563357, COSV51941590; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.416dup p.N139Kfs*3 | Frame Shift Ins (INS) | VAF 53/255 reads (21%) | catalogued as rs759271356; called by mutect2, pindel, varscan2
- ST6GALNAC4 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | PolyPhen benign (0.045); catalogued as COSV59130437; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | PolyPhen probably damaging (0.967); catalogued as rs140558384; called by muse, mutect2, varscan2
- STK39 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs776513083, COSV63600294; called by muse, mutect2, varscan2
- STOML1 | c.1114del p.A372Pfs*3 | Frame Shift Del (DEL) | VAF 59/177 reads (33%) | catalogued as rs769286917; called by mutect2, pindel, varscan2
- STOML1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs1475319090, COSV57552204; called by muse, mutect2, varscan2
- STON2 | c.2177C>T p.A726V (on ENST00000649389 / NM_001366849.2; = p.A669V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774934482, COSV50842461; called by muse, mutect2, varscan2
- STON2 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs1292187120, COSV50851054; called by muse, mutect2, varscan2
- STPG1 | c.150del p.G51Dfs*90 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs1210126972; called by mutect2, varscan2
- STUB1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11642472, COSV50201820; called by muse, mutect2, varscan2
- STXBP4 | c.1211del p.K404Rfs*31 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as COSV64466377; called by mutect2, varscan2
- SUCLG1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67265661; called by muse, varscan2
875 further variants in this file (392 protein-altering or splice-affecting, 356 silent, 127 other) are not listed here.
